Surgical pathology report (de-identified scan), TCGA case TCGA-FJ-A871, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Baylor, specimen TCGA-FJ-A871-01A (Primary Tumor).

[page 1 of 2]
Status: Final result

Results

Entry Date

Component Results

DATE OF DISCHARGE:

DATE OF SERVICE:

Pathology Consultation Report

Final

ANATOMIC PATHOLOGY DIAGNOSIS:

- A . Urinary bladder, right lateral wall tumor, transurethral biopsy
- High grade urothelial carcinoma
- Infiltrating into muscularis propria
- B . Prostatic urethra, transurethral biopsy
- No dysplasia or malignancy

PATHOLOGIST:

I have reviewed this material and confirm the report. Released by
electronic signature on:

MATERIAL:

- A. Bladder tumor right lateral wall
B. Prostatic urethra

HISTORY:

Preoperative Diagnosis: Bladder cancer

GROSS:

A. Received in formalin labeled bladder tumor right lateral wall is a 3.0 x 3.0 x 1.3 cm aggregate of multiple pieces of irregular tan-pink rubbery soft tissue. The specimen is submitted in toto in cassettes A1-6.

B. Received in formalin labeled prostatic urethra is a 2.0 x 1.5 x 0.7 cm aggregate of irregular tan-pink rubbery tissue. The specimen is submitted in toto in cassettes B1-B2.

ICD-3
Carcinoma, urothelial NOS
Site: Bladder, lateral wall
8/20/13
C67.2
Bladder wall NOS
C67.9
JSD 11/29/13

[page 2 of 2]
MICROSCOPIC:

A . Sections of the right lateral wall bladder tumor biopsy show high-grade urothelial carcinoma. The tumor has high mitotic activity, pleomorphism and abundant cytoplasm. The tumor infiltrates the muscularis propria. Abundant necrosis is seen.

B . The prostatic urethra, transurethral biopsy shows unremarkable prostatic parenchyma. The urothelium is unremarkable. No carcinoma in situ or malignancy is identified. In block B2, there is a fragment of tumor with associated muscularis propria. This is interpreted as a floater or contaminant from part A.

INTRADEPARTMENTAL CONSULTATION:

concur with the interpretation in slide B2.

CONSULTING PHYSICIAN:

Page 1 of 1
SURGICAL PATHOLOGY

Lab and Collection

Results Release Comments

Urethra biopsies negative so we are good to go for bladder reconstruction

Patient Release Status:

This result is viewable by the patient in

Last viewed in

By:

Printer Friendly Report

Lab Information

Criteria	W 10/21/13	Yes	No
Reviewer Initials	BC4	Date Reviewed:	10/10/2013

Source: NCI Genomic Data Commons file eee6b393-bee2-4c1e-9334-95b0a321f798 (TCGA-FJ-A871.6F7FA0D6-7A3A-48D2-A45A-326F730E6926.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).